Gene-level copy-number profile of tumor specimen MP2PRT-PAPBZN-TMP1-A from MP2PRT case MP2PRT-PAPBZN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (451 days).
Specimen MP2PRT-PAPBZN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 71ef950a-2c25-4dae-8cb6-e2b49bfc6870.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPBZN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/c005f79c-c909-4176-b2b2-26e0f6445022

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 1,820; copy number 2: 56,417; copy number 3: 21.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,897,784, 11 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2.
- chr2:88,978,468–88,979,081, 1 gene (within-gene range 0–2): IGKV3-7.
- chr7:38,257,879–38,311,808, 7 genes (within-gene range 0–1): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–1): AL772307.1.
- chr9:40,105,822–40,122,540, 2 genes: AL773545.3, CDRT15P14.
- chr9:40,131,747–40,132,218, 1 gene (within-gene range 0–2): AL773545.2.
- chr14:22,438,547–22,459,156, 7 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,511,024, 23 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,851,705–106,258,223, 77 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,820. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
